Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6401, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6401-01A (Primary Tumor).

Anatomic Pathology/Cytology Document State: (version)
Update Date/Time:
Final 1

Patient Name: MRN: Service Date/Time:
DOB/Age/Gender: Female Provider:
Location: Responsible Staff:

PATH.NO:
NAME: MED. REC. NO:
AGE/SEX: F DOB: SURGERY DATE:
RECEIVE DATE:
PHYSICIAN:
COPY TO:

PATHOLOGICAL DIAGNOSIS:

A. AND B. BRAIN, LEFT, EXCISIONAL BIOPSIES: OLIGODENDROGLIOMA,
MIB-1 LABELING INDEX < 1.0%.
SEE MICROSCOPIC DESCRIPTION AND COMMENT.

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx: year old woman with diagnosis 6
months ago of oligodendroglioma. For extensive resection.

GROSS PATHOLOGY:

A. "left tumor", received fresh, one fragment, 0.8 cm. across.
Semifirm, pinkish-gray. In total #1.

INTRAOPERATIVE CONSULTATION: Brain, left: glioma, low grade,
consistent with oligodendroglioma.

B. "left tumor", one fragment, 0.7 cm. across. Soft, pinkish-gray. In
total #2.

INTRAOPERATIVE CONSULTATION: Brain, left: glioma, low grade,
consistent with oligodendroglioma.

MICROSCOPIC: A. and B. Portions of a moderately cellular neoplastic
glial proliferation, in which the cells display uniform round nuclei.
There is moderate nuclear pleomorphism and nuclear hyperchromasia. The
background is finely fibrillary, and the vascular network consists of
capillary-type vessels. Gliofibrillary oligodendrocytes and
minigemistocytes are rarely observed. There are no mitotic figures,
and areas of necrosis or microvascular cellular proliferation are not
observed.

SPECIAL STAINS: Immunoperoxidase methods for GFAP, synaptophysin, and
MIB-1 are performed on block #2.

With the GFAP the tumor cells are not immunoreactive. No tumor cells
immunoreact with synaptophysin. With the MIB-1 a labeling index of
less than 1% is determined.

COMMENT: The neoplasm is a low grade glioma with uniform round
neoplastic nuclei, absent features of anaplasia, and a low MIB-1
labeling index of less than 1%. The nuclear pleomorphism is moderate
and consistent with a Smith's grade B.

TISSUE COMMITTEE CODE: TC1.
BILLING CODES:

ICD0-3
Oligodendroglioma, grade II
9450/3
Site Brain, supratentorial
NOS C71.0
Bth @ Brain NOS
C71.9
9/30/13

Source: NCI Genomic Data Commons file 3f2faf72-d351-4ebb-998e-48398fd5e757 (TCGA-DU-6401.8B65EAA0-2BE6-4648-9CF0-9E97AAB0073C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).